MMRF case MMRF_2125 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/395b6808-e872-47e2-a8aa-e3cb69c57c22

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.6 years (19,958 days); ISS stage: III; Days to last known disease status: 876 days (2.4 years); Days to last follow up: 876 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 294 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 442 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 294 days.
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 455 days (1.2 years); Days to treatment end: 512 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 518 days (1.4 years); Days to treatment end: 609 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 609 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -29 (ECOG 1): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2160 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 64.7 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 7.87 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 34 g/L; Total Protein 11.6 g/dL; Glucose 5.72 mmol/L.
- Day 47 (ECOG 1): M Protein 0.87 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.663 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.5 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 4.02 mmol/L.
- Day 159 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.56 mmol/L.
- Day 236 (ECOG 1): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.745 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.52 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 323 (ECOG 1): M Protein 1.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.682 mg/dL; Immunoglobulin G 20.6 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.09 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 5.89 mmol/L.
- Day 414 (ECOG 1): Hemoglobin 6.94 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 5.23 mmol/L.
- Day 510 (ECOG 1): M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.875 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.62 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 4.79 mmol/L.
- Day 603 (ECOG 1): M Protein 1.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.847 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 5.13 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.24 mmol/L.
- Day 700 (ECOG 1): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.892 mg/dL; Immunoglobulin G 7.01 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.02 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 3.41 mmol/L.
- Day 778 (ECOG 1): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.884 mg/dL; Immunoglobulin G 8.63 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.48 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 5.83 mmol/L.
- Day 876 (ECOG 1): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.31 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -29: Weight: 56 kg; Height: 142 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_2125_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -29 days.
- Sample MMRF_2125_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -29 days.
- Sample MMRF_2125_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -29 days.
